CCDI case PBCNGP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7daffe3d-a4c9-4b9f-b8b4-39201c5585bf

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,016 days).

Biospecimens (3 samples)
- Sample 0DVSBS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVSC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVSCD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
